Somatic mutation profile of tumor specimen MMRF_1790_1_BM_CD138pos (aliquot MMRF_1790_1_BM_CD138pos_T1_KBS5U_L07231) from MMRF case MMRF_1790, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.8 years (28,045 days).
Specimen MMRF_1790_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b942159b-777d-4347-b279-c650cf50c76d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1790_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1790_1_PB_WBC_C3_KBS5U_L07232; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1add4605-58be-49dd-8f77-9ca09ceb67ae

The open-access MAF lists 78 somatic variants for this specimen: 30 protein-altering or splice-affecting, 11 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, 3'UTR 18, Silent 11, Intron 8, 5'UTR 4, 3'Flank 3, Nonsense Mutation 2, RNA 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL7B | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as rs139165156; called by muse, mutect2, varscan2
- ADPRS | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 8/144 reads (6%) | catalogued as rs1191594529; called by muse, mutect2
- ASXL3 | c.6347C>T p.A2116V | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.59); catalogued as rs757112357, COSV52466903, COSV52470266; called by muse, mutect2, varscan2
- CFAP74 | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200040017; called by muse, mutect2, varscan2
- DNAI3 | c.446T>G p.V149G | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs1409802552; called by muse, mutect2, varscan2
- DPP6 | c.692G>A p.S231N (on ENST00000377770 / NM_001364500.2; = p.S169N on NM_001936.5) | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs538699484; called by muse, mutect2
- FRAS1 | c.4951C>T p.R1651* | Nonsense Mutation (SNP) | VAF 23/50 reads (46%) | catalogued as rs753960106, COSV99347169, COSV99347494; called by muse, mutect2, varscan2
- IRF4 | c.296G>C p.C99S | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66705766; called by muse, mutect2, varscan2
- KCNB1 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1338339252, COSV65568401; called by muse, mutect2, varscan2
- LINGO2 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 122/242 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs781520934, COSV58057149; called by muse, mutect2, varscan2
- PRRT4 | c.2389G>A p.A797T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs867388733; called by muse, mutect2, varscan2
- SMYD1 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs534664884, COSV70224922; called by muse, mutect2, varscan2
- AL645922.1 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 73/141 reads (52%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ALAS2 | c.1434C>G p.I478M | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ANKRD35 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH10 | c.1114G>C p.E372Q (on ENST00000409039; = p.E311Q on NM_207437.3) | Missense Mutation (SNP) | VAF 90/212 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IFNAR1 | c.593A>T p.Y198F | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHD1-7 | c.5T>G p.I2R | Missense Mutation (SNP) | VAF 24/26 reads (92%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGSF1 | c.1195A>G p.K399E | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- IGSF10 | c.1173C>A p.S391R | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- KCNN2 | c.1105T>G p.Y369D (on ENST00000264773; = p.Y581D on NM_021614.4) | Missense Mutation (SNP) | VAF 98/252 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- MXRA5 | c.527T>G p.F176C | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- PCDHAC2 | c.1531A>T p.R511W | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- PRKD2 | c.1151T>G p.V384G | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTX4 | c.887C>T p.A296V (on ENST00000447419 / NM_001328608.2; = p.A291V on NM_001013658.1) | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- RETREG1 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, varscan2
- SLU7 | c.1396T>A p.S466T | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- SVEP1 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- TPTE | c.1586C>T p.S529L (on ENST00000618007 / NM_199261.4; = p.S511L on NM_199259.4) | Missense Mutation (SNP) | VAF 168/904 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- USP45 | c.1774G>T p.G592W | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- AC099489.1 | c.3273G>T p.R1091= | Silent (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- ADCY7 | c.822G>A p.R274= | Silent (SNP) | VAF 22/90 reads (24%) | called by muse, mutect2, varscan2
- CLCN6 | c.1920C>T p.R640= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as rs142493749; called by muse, mutect2, varscan2
- GTF3C1 | c.5808T>C p.S1936= | Silent (SNP) | VAF 66/178 reads (37%) | called by muse, varscan2
- MACF1 | c.10332A>G p.Q3444= | Silent (SNP) | VAF 67/142 reads (47%) | called by muse, mutect2, varscan2
- MAGEH1 | c.513G>C p.S171= | Silent (SNP) | VAF 15/241 reads (6%) | catalogued as rs1477245374; called by muse, mutect2
- NSMCE3 | c.222C>T p.A74= | Silent (SNP) | VAF 45/122 reads (37%) | called by muse, mutect2, varscan2
- SMOC2 | c.405G>A p.T135= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs780892063; called by muse, mutect2, varscan2
- UBR4 | c.12219G>A p.K4073= | Silent (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- UNC80 | c.2874C>T p.A958= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs756648889; called by muse, varscan2
- VHL | c.69C>T p.Y23= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV56552344; called by muse, mutect2
- AKAP5 | c.-897G>T | 5'UTR (SNP) | VAF 30/110 reads (27%) | called by muse, mutect2, varscan2
- AKAP5 | c.-806A>C | 5'UTR (SNP) | VAF 18/73 reads (25%) | called by muse, mutect2, varscan2
- AMACR | c.*2267C>T | 3'UTR (SNP) | VAF 23/87 reads (26%) | called by muse, mutect2, varscan2
- APEX2 | c.*1237A>G | 3'UTR (SNP) | VAF 25/93 reads (27%) | called by muse, mutect2
- ARHGEF9 | c.*548T>C | 3'UTR (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2, varscan2
- ARMC10P1 | n.791C>G | RNA (SNP) | VAF 44/121 reads (36%) | called by muse, mutect2, varscan2
- ATF4 | c.-92del | 5'UTR (DEL) | VAF 18/70 reads (26%) | called by pindel, varscan2
- BCL7A | chr12:122021118 C>T | 5'Flank (SNP) | VAF 64/142 reads (45%) | catalogued as COSV55851758; called by muse, mutect2, varscan2
- CASK | chrX:41515648 G>C | 3'Flank (SNP) | VAF 14/65 reads (22%) | called by muse, mutect2, varscan2
- CCNL1 | chr3:157160676 C>A | 5'Flank (SNP) | VAF 17/49 reads (35%) | called by muse, mutect2, varscan2
- CDH12 | c.*364A>T | 3'UTR (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- COL1A2 | c.2404-95C>A | Intron (SNP) | VAF 14/38 reads (37%) | called by muse, varscan2
- CYP2A7P2 | n.494C>T | RNA (SNP) | VAF 71/150 reads (47%) | called by muse, mutect2, varscan2
- ETV1 | chr7:13894071 ins G | 3'Flank (INS) | VAF 31/87 reads (36%) | called by mutect2, pindel, varscan2
- GPR158 | c.-193G>T | 5'UTR (SNP) | VAF 32/77 reads (42%) | catalogued as rs772745398; called by muse, mutect2, varscan2
- HS3ST1 | c.*1286G>A | 3'UTR (SNP) | VAF 44/92 reads (48%) | catalogued as rs1440186295; called by muse, mutect2, varscan2
- KPNB1 | c.1913-165T>A | Intron (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- KRTAP19-5 | c.*143C>T | 3'UTR (SNP) | VAF 42/101 reads (42%) | called by muse, mutect2, varscan2
- MAPK12 | c.255+48G>A | Intron (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- NPNT | c.265+124G>A | Intron (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- PLCB2 | c.3268-72G>T | Intron (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- PRSS40A | n.318-1124G>A | Intron (SNP) | VAF 8/36 reads (22%) | called by mutect2, varscan2
- RAB40C | c.*128C>T | 3'UTR (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2, varscan2
- RNF213 | c.10304-136G>T | Intron (SNP) | VAF 7/104 reads (7%) | called by muse, mutect2
- SEL1L | c.*2717_*2718insC | 3'UTR (INS) | VAF 48/128 reads (38%) | called by pindel, varscan2
- SEL1L | c.*2685T>G | 3'UTR (SNP) | VAF 64/136 reads (47%) | called by muse, varscan2
- SESTD1 | c.*4815A>G | 3'UTR (SNP) | VAF 93/209 reads (44%) | called by muse, mutect2, varscan2
- SH3RF3 | c.*2959G>A | 3'UTR (SNP) | VAF 19/47 reads (40%) | catalogued as rs1303542165; called by muse, mutect2, varscan2
- SHANK3 | c.2009-46C>T | Intron (SNP) | VAF 15/36 reads (42%) | catalogued as rs767314767; called by muse, mutect2, varscan2
- SIM1 | c.*537T>C | 3'UTR (SNP) | VAF 50/119 reads (42%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143627493 A>C | 3'Flank (SNP) | VAF 42/98 reads (43%) | called by mutect2, varscan2
- STK16 | c.*912T>C | 3'UTR (SNP) | VAF 60/133 reads (45%) | called by muse, mutect2, varscan2
- TBX18 | c.*21A>G | 3'UTR (SNP) | VAF 18/48 reads (38%) | catalogued as COSV100858428; called by muse, mutect2, varscan2
- TDO2 | c.*258A>T | 3'UTR (SNP) | VAF 56/120 reads (47%) | called by muse, mutect2, varscan2
- TXNL1 | c.*1904_*1907del | 3'UTR (DEL) | VAF 3/34 reads (9%) | catalogued as rs1241163683; called by mutect2, pindel
- ZFAND4 | c.*613G>C | 3'UTR (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- ZNF142 | c.*4452G>T | 3'UTR (SNP) | VAF 5/100 reads (5%) | catalogued as COSV101346858; called by muse, mutect2
